MMRF case MMRF_2014 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/edc63ede-c4e0-4aad-8a78-239cfd820083

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.7 years (22,537 days); ISS stage: III; Days to last known disease status: 1,010 days (2.8 years); Days to last follow up: 1,010 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 93 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 109 days; Days to treatment end: 109 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 212 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 458 days (1.3 years); Days to treatment end: 711 days (1.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 480 mg/dL; Immunoglobulin G 5.93 g/L; Immunoglobulin A 0.532 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 8.9 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.59 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.28 mmol/L.
- Day 93 (ECOG 2): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 293 mg/dL; Immunoglobulin G 4.67 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 5.12 mmol/L.
- Day 142 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 83.6 mg/dL; Immunoglobulin G 7.9 g/L; Immunoglobulin A 0.728 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 5.89 mmol/L.
- Day 212 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 78.2 mg/dL; Immunoglobulin G 9.27 g/L; Immunoglobulin A 0.384 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.01 mmol/L.
- Day 332 (ECOG 1): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 33.2 mg/dL; Immunoglobulin G 8.58 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 4.9 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.06 ×10⁹/L; Absolute Neutrophil 2.84 ×10⁹/L; Platelets 317 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 5.28 mmol/L.
- Day 458 (ECOG 1): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 42.5 mg/dL; Immunoglobulin G 8.34 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.82 ×10⁹/L; Absolute Neutrophil 1.72 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 4.24 mmol/L.
- Day 521 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 27.5 mg/dL; Beta 2 Microglobulin 3.8 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.84 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 4.29 mmol/L.
- Day 708: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.6 mg/dL; Immunoglobulin G 8.02 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.7 µg/mL; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.44 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.05 mmol/L; Albumin 35 g/L; Total Protein 5.3 g/dL; Glucose 5.06 mmol/L.
- Day 808 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.7 mg/dL; Beta 2 Microglobulin 3.6 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.78 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 6.22 mmol/L.
- Day 890 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 16.4 mg/dL; Beta 2 Microglobulin 3.8 µg/mL; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 0.94 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 1.98 mmol/L; Albumin 35 g/L; Total Protein 5.9 g/dL; Glucose 4.46 mmol/L.
- Day 1,010: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 2.16 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -27: Weight: 126 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2014_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_2014_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -27 days.
